TARGET case TARGET-20-PAWPVR — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b88bf0d6-e23a-4f25-8a53-2738e0aea153

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.3 years (5,605 days); Year of diagnosis: 2014; Days to last follow up: 809 days (2.2 years); Sites of involvement: Central nervous system.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Treatment type: Stem Cell Transplantation, NOS; Timepoint category: First Complete Response.

Follow-up (1 entry)
- Days to follow up: 809 days (2.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 809; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Positive.
- KMT2A translocation: Negative.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- Day 0: Leukocytes 432 ×10³/µL; Blast Count 98%.
- Minimal Residual Disease (Flow Cytometry): Positive.

Biospecimens (1 sample)
- Sample TARGET-20-PAWPVR-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AML1031_20230720.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 809
- WBC at Diagnosis: 432.2
- Peripheral blasts (%): 97.6
- CNS disease: Yes
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: No
- Minus Y: No
- Minus X: No
- Cytogenetic Complexity: 0
- Primary Cytogenetic Code: Normal
- ISCN: 46,XX[20]
- FLT3/ITD positive?: Yes
- FLT3/ITD allelic ratio: 0.8
- NPM mutation: No
- CEBPA mutation: No
- MRD at end of course 1: Yes
- MRD % at end of course 1: 1.4
- MRD at end of course 2: Yes
- CR status at end of course 1: CR
- CR status at end of course 2: unevaluable
- Risk group: High Risk
- SCT in 1st CR: Yes
